Somatic mutation profile of tumor specimen TCGA-B6-A0WX-01A (aliquot TCGA-B6-A0WX-01A-11D-A10G-09) from TCGA case TCGA-B6-A0WX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.5 years (14,784 days).
Specimen TCGA-B6-A0WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62f21ab0-c6ba-4305-b152-d419270004cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0WX-10A (Blood Derived Normal), aliquot TCGA-B6-A0WX-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fdf22a9-b297-445e-b98a-572986c4457b

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 48/118 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.341T>A p.L114* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs781724995, CD084237, COSV52753440; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B4GALT6 | c.765A>C p.K255N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52703272; called by muse, mutect2, varscan2
- BRK1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56541616; called by muse, mutect2, varscan2
- CACNA1H | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs907429190, COSV61988280; called by mutect2, varscan2
- CCN6 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV57889193; called by muse, mutect2, varscan2
- CNR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs201049279; called by muse, mutect2, varscan2
- EFHC2 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV69553499; called by muse, mutect2, varscan2
- EPAS1 | c.2061T>G p.F687L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV55385938; called by muse, mutect2, varscan2
- HSD3B2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs373456025; called by muse, mutect2, varscan2
- IL17RE | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs188907497, COSV55967806; called by muse, mutect2, varscan2
- MTX2 | c.567C>G p.C189W | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50887820; called by muse, mutect2, varscan2
- NCKAP5 | c.5214C>A p.Y1738* | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV58439477; called by muse, mutect2, varscan2
- NRXN2 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV55447551; called by muse, mutect2, varscan2
- PHLDB1 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782797193, COSV61877859; called by muse, mutect2, varscan2
- RAB42 | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV65753011; called by muse, mutect2, varscan2
- SLC34A2 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65941326; called by muse, mutect2, varscan2
- SOCS5 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV60603688; called by muse, mutect2, varscan2
- SRGAP1 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV61896851, COSV61902249; called by muse, mutect2, varscan2
- TAF4B | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs567210583, COSV52303049; called by muse, mutect2, varscan2
- THSD7A | c.1554G>C p.W518C | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70263863; called by muse, mutect2, varscan2
- ZC3H12B | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59047469, COSV59051701; called by muse, mutect2, varscan2
- ZNF43 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV61683645; called by muse, mutect2, varscan2
- ZNF512 | c.768+1G>T p.X256_splice | Splice Site (SNP) | VAF 19/110 reads (17%) | catalogued as COSV62675070; called by muse, mutect2, varscan2
- ZNRF3 | c.1066C>T p.R356C (on ENST00000544604 / NM_001206998.2; = p.R256C on NM_032173.3) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV60433429; called by muse, mutect2, varscan2
- ATXN1 | c.1434G>A p.L478= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs770494841, COSV55214309; called by muse, mutect2, varscan2
- BCL11A | c.1560C>A p.S520= (on ENST00000335712 / NM_001365609.1; = p.S554= on NM_018014.4) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59628440; called by muse, mutect2, varscan2
- BMS1 | c.1866A>G p.Q622= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs890292437, COSV65733631; called by muse, mutect2, varscan2
- EPAS1 | c.1515C>T p.F505= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as rs143242674; called by muse, mutect2, varscan2
- FAM210A | c.18A>G p.P6= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV59184041; called by muse, mutect2, varscan2
- L3MBTL1 | c.2364T>C p.C788= (on ENST00000418998 / NM_001377303.1; = p.C698= on NM_015478.7) | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV64228270; called by muse, mutect2, varscan2
- NRF1 | c.906A>G p.P302= | Silent (SNP) | VAF 45/164 reads (27%) | catalogued as COSV56211627; called by muse, mutect2, varscan2
- SF3B3 | c.2241G>T p.S747= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV56786997; called by muse, mutect2, varscan2
- TEX11 | c.1401C>T p.Y467= (on ENST00000344304; = p.Y452= on NM_031276.3) | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV60229506; called by muse, mutect2, varscan2
- VANGL2 | c.765C>T p.D255= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs772251993, COSV63604316; called by muse, mutect2, varscan2
